Somatic mutation profile of tumor specimen C3L-01453-03 (aliquot CPT0108400009_1) from CPTAC case C3L-01453, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 69.7 years (25,473 days).
Specimen C3L-01453-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a4c93f2-3e6b-4493-a858-db4fc528da06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01453-31 (Blood Derived Normal), aliquot CPT0108330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39a1d305-52c5-4e16-8d65-92d62f512de5

The open-access MAF lists 43 somatic variants for this specimen: 28 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 10, Nonsense Mutation 1, 5'UTR 1, Intron 1, RNA 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 79/629 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 157/1015 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAA1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 51/317 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs751653410; called by muse, mutect2, varscan2
- BRD4 | c.4081C>T p.L1361F | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.905); catalogued as COSV54590178, COSV99650932; called by muse, mutect2
- C20orf173 | c.218C>T p.S73L (on ENST00000246199; = p.S126L on NM_001145350.2) | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1050191157; called by muse, mutect2, varscan2
- CYP4F2 | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 54/340 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs146148233, COSV55616274; called by muse, mutect2, varscan2
- EFCAB12 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 65/492 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs747911030; called by muse, mutect2, varscan2
- LCLAT1 | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 67/605 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs753684188; called by muse, mutect2, varscan2
- LRP1B | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 58/500 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs772492671; called by muse, mutect2, varscan2
- MYO18B | c.6126G>C p.E2042D | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV59129833; called by muse, mutect2, varscan2
- PRG4 | c.3851G>A p.R1284K | Missense Mutation (SNP) | VAF 64/496 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.54); catalogued as COSV63355732; called by muse, mutect2, varscan2
- RALBP1 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 61/493 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as rs780605304; called by muse, mutect2, varscan2
- SMIM7 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 90/851 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); catalogued as rs956924929; called by muse, mutect2, varscan2
- SP140 | c.2512G>C p.D838H | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV59446738; called by muse, mutect2, varscan2
- SYPL1 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 48/280 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.902); catalogued as rs773642336; called by muse, mutect2, varscan2
- TLL1 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 84/596 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1207038779; called by muse, mutect2, varscan2
- TRPC4AP | c.1960C>A p.R654S | Missense Mutation (SNP) | VAF 83/504 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.565); catalogued as rs371612752; called by muse, mutect2, varscan2
- TTN | c.62659G>T p.E20887* (on ENST00000591111; = p.E13463* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 75/726 reads (10%) | catalogued as COSV60232343; called by muse, mutect2, varscan2
- ZNF3 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 66/1040 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1452184063; called by muse, mutect2
- ADGRV1 | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 51/366 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- DPYSL3 | c.398G>C p.C133S | Missense Mutation (SNP) | VAF 58/455 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- HLTF | c.1012T>G p.S338A | Missense Mutation (SNP) | VAF 36/391 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- PTPN6 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 53/406 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- SLIT3 | c.2722C>T p.P908S | Missense Mutation (SNP) | VAF 53/431 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- SQOR | c.884C>G p.T295R | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TRIM72 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- TRPC3 | c.152C>G p.S51W | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); called by muse, mutect2
- ZNF7 | c.1212G>C p.Q404H | Missense Mutation (SNP) | VAF 131/623 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- GTF3C2 | c.1149T>C p.H383= | Silent (SNP) | VAF 46/313 reads (15%) | called by muse, mutect2, varscan2
- HGF | c.1578G>A p.E526= | Silent (SNP) | VAF 88/589 reads (15%) | catalogued as COSV55949285; called by muse, mutect2, varscan2
- MUC17 | c.8811C>T p.T2937= | Silent (SNP) | VAF 24/477 reads (5%) | catalogued as rs530486985, COSV60282250; called by muse, mutect2
- P3H1 | c.180G>A p.R60= | Silent (SNP) | VAF 59/518 reads (11%) | called by muse, mutect2, varscan2
- PCSK1 | c.471G>A p.T157= | Silent (SNP) | VAF 163/1262 reads (13%) | catalogued as rs780582982, COSV100227229; called by muse, mutect2, varscan2
- SLC16A3 | c.564C>T p.L188= | Silent (SNP) | VAF 16/159 reads (10%) | catalogued as rs1414755478, COSV66429952; called by muse, mutect2, varscan2
- TLE2 | c.504G>A p.A168= | Silent (SNP) | VAF 65/750 reads (9%) | catalogued as rs781758361; called by muse, mutect2
- WDR59 | c.1179G>A p.Q393= | Silent (SNP) | VAF 69/578 reads (12%) | called by muse, mutect2, varscan2
- WDR90 | c.2208C>T p.Y736= | Silent (SNP) | VAF 27/179 reads (15%) | catalogued as rs372511115; called by muse, mutect2, varscan2
- ZBTB32 | c.102C>T p.T34= | Silent (SNP) | VAF 41/396 reads (10%) | catalogued as rs267605432, COSV52891935; called by muse, mutect2, varscan2
- BCKDK | c.*138T>C | 3'UTR (SNP) | VAF 43/325 reads (13%) | catalogued as rs553418699; called by muse, mutect2, varscan2
- FAM98B | chr15:38484295 A>C | 3'Flank (SNP) | VAF 65/614 reads (11%) | called by muse, mutect2, varscan2
- MAST4 | c.642+40053G>A | Intron (SNP) | VAF 46/450 reads (10%) | catalogued as rs914001649; called by muse, mutect2, varscan2
- RPL13AP20 | n.505C>T | RNA (SNP) | VAF 94/861 reads (11%) | catalogued as rs752535332; called by muse, mutect2, varscan2
- SP140 | c.-24C>T | 5'UTR (SNP) | VAF 74/700 reads (11%) | catalogued as rs750475076, COSV100613452; called by muse, mutect2, varscan2
